Gene-level copy-number profile of tumor specimen TCGA-BR-7723-01A from TCGA case TCGA-BR-7723, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 59.8 years (21,839 days).
Specimen TCGA-BR-7723-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.fc5b9ac8-df65-4c55-8cd8-93c4b2866382.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-7723-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/387a0d6c-aed4-4b83-9a30-5710fe467b61

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 16; copy number 2: 6,187; copy number 3: 15,689; copy number 4: 20,311; copy number 5: 6,800; copy number 6: 6,726; copy number 7: 2,424; copy number 8: 20; copy number 9: 831; copy number 10: 121; copy number 11: 312; copy number 12: 231; copy number 13: 55; copy number 14: 7; copy number 15: 14; copy number 17: 11; copy number 41: 6; copy number 42: 7; copy number 45: 11; copy number 58: 27.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-7723-01A-11D-2052-01): tumor purity 0.55, ploidy 4.17, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:14,554,384–14,636,524, 1 gene (within-gene range 0–2): MACROD2-IT1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,633 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:206,747,980–207,150,281, 17 genes, copy number 12: Y_RNA, IL10, IL19, IL20, IL24, FCMR, AC098935.2, AC098935.1, PIGR, FCAMR, C1orf116, PFKFB2, YOD1, C4BPB, C4BPA, AL445493.3, AL445493.1.
- chr1:234,593,275–234,736,720, 10 genes, copy number 9: U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, AL160408.6, LINC01132.
- chr3:136,336,236–175,810,548, 582 genes, copy number 9–11 (within-gene range 6–11) (broad region; genes not listed).
- chr3:175,079,307–188,154,057, 275 genes, copy number 9–11 (broad region; genes not listed).
- chr3:188,178,543–188,180,812, 1 gene, copy number 9: FLJ42393.
- chr3:188,941,715–198,222,513, 217 genes, copy number 9–11 (broad region; genes not listed).
- chr6:46,997,708–47,042,350, 1 gene, copy number 10: ADGRF1.
- chr11:111,245,726–111,455,630, 7 genes, copy number 14 (within-gene range 6–14): C11orf53, COLCA1, COLCA2, AP002448.1, MIR4491, POU2AF1, RNU2-60P.
- chr17:41,712,331–41,865,423, 11 genes, copy number 45: GAST, HAP1, RNA5SP442, RN7SL399P, JUP, P3H4, FKBP10, NT5C3B, KLHL10, AC125257.1, KLHL11.
- chr19:27,638,483–27,984,984, 14 genes, copy number 9–42: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1.
- chr19:29,205,320–30,085,893, 27 genes, copy number 58: UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5.
- chr20:22,263,065–24,680,991, 66 genes, copy number 13–17 (broad region; genes not listed).
- chr20:31,567,707–33,023,703, 53 genes, copy number 9: HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, AL121897.1, KIF3B, AL121583.1, ASXL1, NOL4L, AL034550.1, AL034550.3, AL034550.2, AL133343.2, NOL4L-DT, AL133343.1, C20orf203, FO393400.1, BAK1P1, COMMD7, DNMT3B, MAPRE1, AL035071.2, AL035071.1, EFCAB8, SUN5, BPIFB2.
- chr20:33,811,348–44,842,539, 271 genes, copy number 10–12 (within-gene range 6–12) (broad region; genes not listed).
- chr20:53,668,697–53,875,557, 4 genes, copy number 11: RNU7-14P, AC005914.1, AC006076.1, SUMO1P1.
- chr20:63,337,339–64,313,132, 63 genes, copy number 10 (broad region; genes not listed).
- chr21:27,358,885–28,743,291, 14 genes, copy number 15: AP001605.1, AP001604.1, EIF4A1P1, RPL10P1, NCSTNP1, LINC01673, LINC00113, AJ006995.1, LINC00314, LINC01697, LINC01695, AF165147.1, LINC00161, U6.

Autosomal genes at a single copy (total copy number 1): 16. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
